Somatic mutation profile of tumor specimen TCGA-DC-6155-01A (aliquot TCGA-DC-6155-01A-11D-1657-10) from TCGA case TCGA-DC-6155, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 31.2 years (11,381 days).
Specimen TCGA-DC-6155-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 411b91ec-960c-4663-b543-bb70fec8e085.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DC-6155-10A (Blood Derived Normal), aliquot TCGA-DC-6155-10A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38d274ea-6201-4e97-b89c-168cce1c2c82

The open-access MAF lists 58 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 14, Splice Site 2, RNA 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 44/157 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.2843G>A p.R948Q (on ENST00000404938 / NM_001163941.2; = p.R503Q on NM_178559.6) | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.178); catalogued as rs200559589, COSV51720897; called by muse, mutect2, varscan2
- ACTN1 | c.295T>G p.F99V | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99518578; called by muse, mutect2, varscan2
- ANKS1B | c.3038G>A p.R1013Q | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as rs1252788622, COSV59116505; called by muse, mutect2
- ASIC4 | c.1388C>G p.T463S (on ENST00000347842 / NM_182847.3; = p.T482S on NM_018674.6) | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV61731905; called by muse, mutect2, varscan2
- C5orf38 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); catalogued as COSV57411331; called by muse, mutect2, varscan2
- CACNA1B | c.1309C>T p.R437W | Missense Mutation (SNP) | VAF 40/167 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as rs761233759, COSV53127514; called by muse, mutect2, varscan2
- CACNG3 | c.662T>G p.F221C | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV50071479, COSV99137223; called by muse, varscan2
- CASKIN2 | c.2692G>A p.G898R | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV58596019; called by muse, mutect2, varscan2
- CDC20B | c.780C>G p.N260K | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV57052809; called by muse, mutect2, varscan2
- CDK20 | c.315G>C p.K105N | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV57482841; called by muse, mutect2, varscan2
- CHRNA4 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as rs144716263, COSV100937420; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DACH1 | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV100499351; called by muse, mutect2, varscan2
- DISP2 | c.3413A>G p.D1138G | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.05); catalogued as COSV99140562; called by muse, mutect2, varscan2
- ERICH3 | c.2255C>T p.A752V | Missense Mutation (SNP) | VAF 67/288 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV100445902; called by muse, mutect2, varscan2
- FBXL16 | c.377G>A p.R126H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as rs763316306, COSV60964561; called by muse, mutect2, varscan2
- FGF13 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); catalogued as COSV65434192; called by muse, mutect2
- FLRT2 | c.1136C>T p.P379L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.419); catalogued as rs771456284, COSV58142076; called by muse, mutect2, varscan2
- GALNT2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.026); catalogued as rs369808855, COSV64192997; called by muse, mutect2, varscan2
- GPKOW | c.398T>A p.I133N | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV50242796; called by muse, mutect2, varscan2
- GPR149 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs199967865, COSV67667010; called by muse, mutect2, varscan2
- HYDIN | c.13925G>A p.R4642H | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765529216, COSV66639404; called by muse, varscan2
- ICA1 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1432548056, COSV55579234; called by muse, mutect2, varscan2
- IMPG2 | c.501+2T>C p.X167_splice | Splice Site (SNP) | VAF 12/72 reads (17%) | catalogued as COSV51978823; called by mutect2, varscan2
- KCNF1 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1292006652, COSV54462857; called by muse, varscan2
- LAMA1 | c.5503G>C p.E1835Q | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV67537734; called by muse, mutect2, varscan2
- MAK16 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as COSV100659828; called by muse, varscan2
- NIBAN1 | c.172T>A p.F58I | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV62284978; called by muse, varscan2
- NKAIN4 | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as COSV99417017; called by muse, mutect2
- PRICKLE1 | c.2206C>A p.H736N | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV58207216, COSV58210377; called by muse, mutect2, varscan2
- S1PR4 | c.682C>T p.R228C | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs766414904, COSV55740349; called by muse, mutect2, varscan2
- SEMA3G | c.592C>T p.R198* | Nonsense Mutation (SNP) | VAF 19/34 reads (56%) | catalogued as rs759458121, COSV51595880; called by muse, mutect2, varscan2
- SLC1A4 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52234635; called by muse, mutect2, varscan2
- SYDE1 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1208777718, COSV61442225; called by muse, mutect2, varscan2
- TFDP3 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.44); PolyPhen benign (0.013); catalogued as rs765029523, COSV59536978; called by muse, mutect2, varscan2
- TGIF1 | c.184-1G>A p.X62_splice (on ENST00000330513 / NM_001374396.1; = p.X82_splice on NM_003244.4) | Splice Site (SNP) | VAF 8/21 reads (38%) | catalogued as COSV100395018; called by muse, mutect2
- TIAM1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as rs760273681, COSV54545046; called by muse, mutect2, varscan2
- TMC3 | c.1645T>C p.F549L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100845894, COSV63922124, COSV63923281; called by mutect2, varscan2
- WNK3 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 57/242 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100672184; called by muse, mutect2, varscan2
- WNT4 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV51603801; called by muse, mutect2
- MAGEB6B | c.119C>G p.S40C | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRKAR2B | c.521del p.L174Wfs*8 | Frame Shift Del (DEL) | VAF 42/179 reads (23%) | called by mutect2, pindel, varscan2
- TRGC1 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 54/332 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, varscan2
- CPAMD8 | c.4578G>A p.V1526= (on ENST00000651564; = p.V1479= on NM_015692.5) | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV71596326, COSV71596637; called by muse, mutect2, varscan2
- CTNNA2 | c.702C>T p.A234= | Silent (SNP) | VAF 39/65 reads (60%) | catalogued as rs779761149, COSV63569973; called by muse, mutect2, varscan2
- DNAI2 | c.822G>A p.S274= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as rs140295057; called by muse, mutect2, varscan2
- GLI2 | c.1083C>T p.A361= | Silent (SNP) | VAF 65/260 reads (25%) | catalogued as rs138680216; called by muse, mutect2, varscan2
- HJURP | c.1695A>G p.P565= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV100982642; called by muse, mutect2
- KRTAP5-8 | c.351C>G p.S117= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV68324621; called by muse, varscan2
- LAMA1 | c.7926G>A p.S2642= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs1375658475, COSV101057854; called by muse, mutect2, varscan2
- LBP | c.513G>A p.S171= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs760833819, COSV54140538; called by muse, mutect2, varscan2
- NCKAP5 | c.2958G>A p.P986= | Silent (SNP) | VAF 105/216 reads (49%) | catalogued as rs189440819; called by muse, mutect2
- PHACTR3 | c.1134G>A p.L378= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100733271; called by muse, mutect2
- SYNE1 | c.23811G>A p.E7937= (on ENST00000367255 / NM_182961.4; = p.E7866= on NM_033071.3) | Silent (SNP) | VAF 83/167 reads (50%) | catalogued as COSV54992953; called by muse, mutect2, varscan2
- TENM3 | c.5103C>T p.D1701= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as rs369200143; called by muse, mutect2, varscan2
- THOC2 | c.699A>G p.E233= | Silent (SNP) | VAF 46/479 reads (10%) | catalogued as rs770539761, COSV55546473, COSV99832667; called by muse, mutect2
- ZNF415 | c.615A>G p.Q205= | Silent (SNP) | VAF 44/301 reads (15%) | catalogued as COSV54701582; called by muse, mutect2, varscan2
- MIR29C | n.17G>A | RNA (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
